Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8588, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8588-01A (Primary Tumor).

[page 1 of 5]
[REDACTED]

[REDACTED] Case ID	Gross Description
[REDACTED]	

[page 2 of 5]
Microscopic Description	Diagnosis Details

[page 3 of 5]
Comments	Formatted Path Report
	STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Fundus Tumor size: 5 x 6 x 1.2 cm Tumor features: Ulcerated, Annular Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Serosa (visceral peritoneum) Lymph nodes: 0/6 positive for metastasis (Regional 0/6) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 4 of 5]
ID

114

[page 5 of 5]
Excision date

Source: NCI Genomic Data Commons file aa6fc72f-03af-4e4d-ba74-2fea31686e52 (TCGA-BR-8588.8C9DDBC4-9745-41FE-B03C-CACCACFF4A5A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).